TCGA case TCGA-14-1454 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Emory University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c2399f5d-dc29-42e9-81f1-1d164d4cc55d

Demographics
Sex at birth: female; Race: white; Age at index: 54 years; Vital status: Dead; Days to death: 918 days (2.5 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 54.4 years (19,887 days); Year of diagnosis: 2005; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Treatment intent type: Adjuvant; Days to treatment start: 0 days; Treatment dose: 8 Wafer.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Treatment intent type: Adjuvant; Days to treatment start: 0 days.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 78 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 235 days; Number of cycles: 7; Treatment dose: 15,370 mg; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Dexamethasone; Initial disease status: Progressive Disease; Days to treatment start: 291 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Hydroxyurea; Initial disease status: Progressive Disease; Days to treatment start: 309 days; Days to treatment end: 900 days (2.5 years); Number of cycles: 18; Treatment dose: 590,000 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Imatinib Mesylate; Initial disease status: Progressive Disease; Days to treatment start: 309 days; Days to treatment end: 900 days (2.5 years); Number of cycles: 18; Treatment dose: 236,000 mg; Route of administration: Oral.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 55.2 years (20,178 days); Days to diagnosis: 291 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 291 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 291 days.
- Days to follow up: 918 days (2.5 years); Disease response: With Tumor.
- Karnofsky performance status: 60; Timepoint: Other.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-14-1454-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.6; Shortest dimension: 0.2.
  Slide TCGA-14-1454-01A-01-BS1: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 0.
  Slide TCGA-14-1454-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0.
- Sample TCGA-14-1454-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-14-1454-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment 1: Pharmaceutical therapy drug name: Gliadel.
- Drug treatment 1, Route of administrations: Route of administration: Other (specify below).
- Drug treatment 2: Therapy regimen: Progression.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 5: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 6: Pharmaceutical therapy drug name: Gleevac; Therapy regimen: Progression.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Subject positive for neoadjuvant therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 918 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 918 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 291 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-14-1454-01): tumor purity 0.95, ploidy 3.03, whole-genome doublings 1 (call status: snp_call).
